Surgical pathology report (de-identified scan), TCGA case TCGA-61-2109, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2109-01A (Primary Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

RIGHT OVARY:

- POORLY DIFFERENTIATED ADENOCARCINOMA WITH SEROUS AND CLEAR CELL FEATURES OF RIGHT OVARY WITH EXTENSION TO RIGHT PARATUBAL TISSUE

B) LEFT OVARY:

- POORLY DIFFERENTIATED ADENOCARCINOMA OF LEFT OVARY
- UNREMARKABLE LEFT FALLOPIAN TUBE

C) UTERUS, 115 GRAMS:

- UNREMARKABLE CERVIX
- PROLIFERATIVE ENDOMETRIUM
- ADENOMYOSIS
- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING CERVICAL AND UTERINE SEROSA

D) OMENTUM:

- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA OF OMENTUM

Source: NCI Genomic Data Commons file 1c414242-4281-4a13-acde-b01209aca808 (TCGA-61-2109.C16BFE93-016F-49D4-8895-05B9055344C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).